CPTAC case C3L-04071 — Bronchus and lung — Squamous Cell Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/39ad94db-bfc7-4cf1-92ab-00ba05e1da0a

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1948; Vital status: Alive; Country of birth: United States.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Upper lobe, lung; Age at diagnosis: 69.3 years (25,328 days); Year of diagnosis: 2018; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T2a; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IB; Tumor grade: G3; Residual disease: R0; Days to last known disease status: 1,909 days (5.2 years); Progression or recurrence: no; Days to last follow up: 1,909 days (5.2 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 2.9 cm; Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 6; Margin status: Uninvolved.

Follow-up (4 entries)
- Days to follow up: 357 days; Disease response: With Tumor; ECOG performance status: 0.
- Days to follow up: 865 days (2.4 years); Disease response: With Tumor.
- Days to follow up: 1,144 days (3.1 years); Progression or recurrence: Yes; Days to recurrence: 271 days.
- Follow-up contacts recording only the day: day 1,532, day 1,909.

Other clinical attributes
- Weight: 78.93 kg; Height: 177.8 cm; BMI: 24.96; FEV1/FVC before bronchodilator (%): 39; FEV1 before bronchodilator (% of reference): 53.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 79.5; Cigarettes per day: 30; Tobacco smoking onset year: 1964; Tobacco smoking quit year: 2017; Alcohol history: Yes; Alcohol intensity: Heavy Drinker; Exposure duration years: 53.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-04071-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 27 days; Initial weight: 165 mg; Time between excision and freezing: 27 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-04071-23: Section location: Right Upper Lobe; Percent tumor nuclei: 50; Percent necrosis: 0.
- Sample C3L-04071-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 27 days; Initial weight: 123 mg; Time between excision and freezing: 29 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-04071-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 27 days; Method of sample procurement: Blood Draw.
